TCGA case TCGA-K7-A5RF — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: ABS - Lahey Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3134f7d1-3359-497a-b8be-1f317d8ddaaa

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Alive.

Diagnoses (3)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 64.5 years (23,557 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin; Days to treatment start: 240 days; Embolic agent: Plastic Beads.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin; Days to treatment start: 275 days; Embolic agent: Plastic Beads.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Hepatocellular carcinoma, NOS: ICD-O-3 morphology code: 8170/3; Tissue or organ of origin: Liver; Classification of tumor: Synchronous primary; Age at diagnosis: 64.3 years (23,496 days); Days to diagnosis: -61 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS.
3. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 65.1 years (23,762 days); Days to diagnosis: 205 days; Prior treatment: Yes.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease.

Follow-up (3 entries)
- Day 205 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 205 days.
- Days to follow up: 240 days; Disease response: With Tumor.
- Days to follow up: 631 days (1.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Alpha Fetoprotein 5 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 75 kg; Height: 177 cm; BMI: 23.9.
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis C Infection; Viral hepatitis serology tests: Hepatitis C Virus RNA.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-K7-A5RF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 1,350 mg.
  Slide TCGA-K7-A5RF-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 14; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-K7-A5RF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-K7-A5RF-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-K7-A5RF-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,010 mg.
  Slide TCGA-K7-A5RF-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 80; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Single.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis C Virus RNA.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free.
- Ablations, Ablation, Ablation treatments: Ablation performed indicator: No.
- Ablations, Ablation, Embolization treatments: Embolization performed indicator: Yes.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy histological type: Hepatocellular Carcinoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 631 days; disease-specific survival: no event (censored), 631 days; disease-free interval: event (new tumor event after initially disease-free), 205 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 205 days.
